Surgical pathology report (de-identified scan), TCGA case TCGA-A3-3311, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A3-3311-01A (Primary Tumor).

[page 1 of 2]
Print Date/Time:

Surgical Pathology

Histopathological Examination

Path#: [REDACTED]
Collected: [REDACTED] Received: [REDACTED] Complete: [REDACTED]

Pre-Op Diagnosis : Right Renal Mass
Order Physician : [REDACTED]
Specimens : Kidney, Right
Frozen Diagnosis :

Report : GROSS EXAMINATION.

The specimen is received in a container labeled with the name of the patient and labeled as kidney, right and adrenal. The specimen consists of a kidney and attached perinephric fat. The kidney stripped of fat measures 13 x 8 x 5.5 cm and weighs 282 g. The ureter and vascular margins of resection are submitted in block one. The capsule strips with ease. The kidney is bivalved and shows an oval golden yellow mass measuring 5.5 x 4.0 x 4.0 cm. This mass is in the lower pole of the kidney. The mass does not grossly involve the capsule. Sections of the capsule are submitted in block two. Sections of the mass are submitted in blocks 3-6. The pelvis and calyces are not grossly dilated. The cortex averages 0.7 cm. There is a cortical cyst measuring 4 cm. Sections of the cyst are submitted in block 7. A random section of kidney is submitted in block 8. Sectioning into the attached fat shows an adrenal gland measuring 7.0 x 2.3 x 0.8 cm. Sections of the adrenal are submitted in blocks nine and 10. [REDACTED]

DIAGNOSIS BASED ON GROSS AND MICROSCOPIC EXAMINATION:

SPECIMEN TYPE: Radical nephrectomy, right kidney.
TUMOR SITE: Lower pole.
FOCALITY: Unifocal.
TUMOR SIZE (LARGEST TUMOR IF MULTIPLE) Greatest dimension: 5.5 cm.
ADDITIONAL DIMENSIONS: 4.0 x 4.0 cm.
MACROSCOPIC EXTENT OF TUMOR: Tumor limited to kidney.
HISTOLOGIC TYPE: Clear cell (conventional) renal carcinoma.
HISTOLOGIC GRADE (FUHRMAN NUCLEAR GRADE): Predominant grade II with a focal area of grade IV (the grade IV component occupies approximately 5% of the tumor examined.).

THIS CONFIDENTIAL AND PRIVILEGED DOCUMENT/INFORMATION IS PROTECTED BY
FEDERAL AND STATE LAW. UNAUTHORIZED DISCLOSURE, DISSEMINATION
OR DUPLICATION IS PROHIBITED

Path
Visit

Page 1 of 2

[page 2 of 2]
EXTENT OF INVASION

PRIMARY TUMOR (PT): pT1b: Tumor more than 4 cm, but not more than 7 cm in greatest dimension, limited to the kidney.
REGIONAL LYMPH NODES (PN): pNX: Cannot be assessed.
DISTANT METASTASIS (PM): pMX: Cannot be assessed.
MARGINS: Margins uninvolved by invasive carcinoma.
ADRENAL GLAND: Present and uninvolved by tumor.
VENOUS (LARGE VESSEL) INVASION (V): Absent.
LYMPHATIC (SMALL VESSEL) INVASION (L): Absent.
ADDITIONAL PATHOLOGIC FINDINGS: Renal cortical cyst.
Focal mild chronic interstitial inflammation.
[T-71000 M-83103 189.0 P3-44070]

Intradepartmental consultation was obtained.

Ptnm: pT1bNXMX.

[REDACTED]

[REDACTED]

Electronically Signed by:

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file ed83e8ae-3177-4142-ae46-c734b07b0356 (TCGA-A3-3311.46081368-F68B-4375-9CE7-580EEDB3862A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).